MMRF case MMRF_1576 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/1aa3e9f5-ec54-4748-a046-9551fb00c8f1

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 68 years; Vital status: Dead; Days to death: 41 days; Cause of death: Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 68.9 years (25,178 days); ISS stage: III; Days to last known disease status: 41 days; Days to last follow up: 41 days.
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 21 days.

Follow-up (2 entries)
- Days to follow up: -1 day; ECOG performance status: 2.
- Follow-up contact recording only the day: day 41.

Molecular and laboratory tests (values rounded to 3 significant figures where GDC's unit conversion carried more)
- Creatinine 177 µmol/L.
- Serum Free Immunoglobulin Light Chain, Kappa 745 mg/dL.
- Glucose 3.69 mmol/L.
- C-Reactive Protein 2.1 mg/dL.
- M Protein 0.2 g/dL.
- Hemoglobin 5.15 mmol/L.
- Immunoglobulin G 6.58 g/L.
- Leukocytes 7.4 ×10⁹/L.
- Albumin 42 g/L.
- Beta 2 Microglobulin 10.1 µg/mL.
- Total Protein 7.4 g/dL.
- Immunoglobulin M 0.27 g/L.
- Blood Urea Nitrogen 5.36 mmol/L.
- Lactate Dehydrogenase 3.2 µkat/L.
- Serum Free Immunoglobulin Light Chain, Lambda 0.975 mg/dL.
- Calcium 2.95 mmol/L.
- Immunoglobulin A 0.53 g/L.
- Platelets 281 ×10⁹/L.

Other clinical attributes
- Day -1: Weight: 58 kg; Height: 149 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_1576_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -1 day.
- Sample MMRF_1576_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -1 day.
